Surgical pathology report (de-identified scan), TCGA case TCGA-32-4208, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-4208-01A (Primary Tumor).

[page 1 of 2]
ADDENDUM DISCUSSION:

Approximately half of the tumor cells demonstrate immunoreactivity for MGMT, with a higher percentage near areas of necrosis.

ADDENDUM DIAGNOSIS:**1, 2. LEFT FRONTAL LESION, BIOPSY AND RESECTION:****GLIOBLASTOMA.**

- TUMOR CELLS POSITIVE FOR MGMT EXPRESSION.

Dictated by:

Verified by:

ACCESSION#:

NEUROPATHOLOGY REPORT**SPECIMEN SOURCE:**

1. Left frontal lesion
2. Tumor

CLINICAL DIAGNOSIS:

Large frontal tumor

GROSS DESCRIPTION:

1. Received fresh for frozen section are two fragments of tan-pink soft tissue aggregating to 0.9 x 0.8 x 0.3 cm. A smear preparation is performed and the specimen is entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The remaining previously frozen soft tissue is subsequently submitted for permanent sections.

[page 2 of 2]
NEUROPATHOLOGY REPORT

GROSS DESCRIPTION:

2. Received in formalin labeled with the patient's name and "tumor" are multiple portions of tan-pink to red hemorrhagic soft tissue grossly consistent with brain ranging in size from 0.5 to 3.3 cm in greatest dimension and aggregating to 8.8 x 5.6 x 1.5 cm. Representative sections are submitted in three cassettes.

One half of a specimen is sent to [REDACTED]
[REDACTED]

MICROSCOPIC DESCRIPTION:

1, 2. Sections demonstrate a markedly hypercellular glial neoplasm that diffusely infiltrates the gray and white matter. The neoplastic cells resemble moderately to markedly atypical fibrillary and pneumocystic astrocytes. Numerous mitotic figures, including many atypical forms are present. Both microvascular proliferation and confluent tumor necrosis are seen.

DIAGNOSIS:

(PROVISIONAL)

1, 2. LEFT FRONTAL LESION, BIOPSY AND RESECTION:
GLIOBLASTOMA, PENDING ADDITIONAL STUDIES.

[REDACTED]
[REDACTED] Dictated by: [REDACTED]
Verified by: [REDACTED]

Source: NCI Genomic Data Commons file 56554866-dade-4d07-8969-87af45d2ea75 (TCGA-32-4208.57687E5D-5795-48A3-A191-CD61E6C981FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).